Gene-level copy-number profile of specimen HCM-BROD-0111-C25-85A from HCMI case HCM-BROD-0111-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 67.5 years (24,655 days).
Specimen HCM-BROD-0111-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file db5ad7ce-8127-4c0e-86a7-8f59e38491f5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0111-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/c8b71e8b-b91b-4730-9248-06512f5f1bf0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,521; copy number 2: 16,523; copy number 3: 29,454; copy number 4: 7,684; copy number 5: 2,361; copy number 6: 1,039; copy number 7: 4; copy number 8: 258; copy number 9: 42; copy number 10: 15.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 319 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:121,380,137–141,344,621, 257 genes, copy number 8 (broad region; genes not listed).
- chr18:59,360,700–59,973,207, 14 genes, copy number 7–10: AC016229.2, CCBE1, AC016229.1, AC090213.1, AC010776.1, AC010776.2, AC010776.3, RPS26P54, GLUD1P4, AC098847.1, PMAIP1, AC107990.1, NFE2L3P1, RN7SL342P.
- chr18:75,696,044–77,993,731, 48 genes, copy number 9–10: LINC01898, AC021506.1, AC021506.2, AC090457.1, AC011095.1, AC103808.6, LINC01893, AC103808.2, AC103808.4, AC103808.3, AC103808.1, AC103808.5, ZNF516, AC009716.1, AC009716.2, AC018413.1, ZNF516-DT, LINC00683, AC034110.1, LINC01927, LINC01879, ARL2BPP1, CCND3P2, AC139085.1, ZNF236-DT, RNU6-346P, AC027575.2, ZNF236, RPL26P35, Metazoa_SRP, AC027575.1, AC093330.1, MBP, AC093330.2, AC093330.3, AC018529.1, AC018529.3, AC018529.2, AC100863.1, GALR1, AC124254.2, AC124254.1, BDP1P, AC123786.1, AC123786.2, RNA5SP461, LINC01029, AC134978.1.

Autosomal genes at a single copy (total copy number 1): 646. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
